Surgical pathology report (de-identified scan), TCGA case TCGA-Z6-AAPN, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Cureline, specimen TCGA-Z6-AAPN-01A (Primary Tumor).

Case #

Patient: **Age (years):** **Gender:** **Male**

Clinical diagnosis: Anaplastic Squamous cell carcinoma of the esophagus

Date of procurement:

Sample: histology #

Gross description: Esophageal fragment with gastric 25x20x20. Section reveals gray tumor mass 1 cm in thickness. Paraesophageal lymphatic node 1,5x0,4 cm with dark-red surface .

Microscopic description: Sections reveal ulcerative infiltrated tumor, anaplastic squamous cell carcinoma with heavy lymphoid infiltration. Surgical borders are clear. Paraesophageal lymphatic node shows metastatic cells. Paragastric lymphatic nodes and greater omentum show no sign of metastasis.

Final diagnosis: Anaplastic Squamous cell carcinoma of the esophagus

ICD-O-3
Carcinoma, anaplastic, squamous cell
(8021/3) (8070/3)
Code to highest 8070/3
Site: ^{C15.5} Esophagus, distal third
^{C15.9} Esophagus NOS C15.9
JAV 4/22/14

Orig. path returned 4/10/14

Source: NCI Genomic Data Commons file 689dc817-4676-4ab8-84a9-09a4eea07216 (TCGA-Z6-AAPN.75067A62-80E7-4AE9-B43D-6991CDCF8F99.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).